Somatic mutation profile of tumor specimen C3N-00512-01 (aliquot CPT0078160007_1) from CPTAC case C3N-00512, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 42.6 years (15,559 days).
Specimen C3N-00512-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf73fd04-3442-4b55-84ef-4ee2a8decc4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00512-31 (Blood Derived Normal), aliquot CPT0078220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8257ff0c-297e-439d-ac52-b2546265e3af

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP13 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 29/537 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV63456387; called by muse, mutect2
- CDKN2A | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 50/1082 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM097979; called by muse, mutect2
- FAM71E1 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1237243194, COSV58541729; called by muse, mutect2
- KIR2DL4 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 26/696 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.856); catalogued as rs753127334; called by muse, mutect2
- LAMA1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 34/710 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as rs149357158; called by muse, mutect2
- MC5R | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1289537923, COSV61254486; called by muse, mutect2
- MISP | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1327279113; called by muse, mutect2
- PCDHGA2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 20/343 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1389707234, COSV53989059; called by muse, mutect2
- SFMBT2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 22/830 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868339582; called by muse, mutect2
- SHROOM2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1398194619, COSV66604211; called by muse, mutect2
- BBS5 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 12/386 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.163); called by muse, mutect2
- CPEB2 | c.2432C>A p.P811Q | Missense Mutation (SNP) | VAF 13/401 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCAM1 | c.327C>T p.T109= | Silent (SNP) | VAF 13/412 reads (3%) | catalogued as rs375471455, COSV100376724, COSV100376819; called by muse, mutect2
- PRDM14 | c.69G>A p.P23= | Silent (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- RYR1 | c.14718G>A p.A4906= | Silent (SNP) | VAF 47/832 reads (6%) | catalogued as rs575960373; ClinVar: likely benign; called by muse, mutect2
- AC020907.6 | c.-347C>A | 5'UTR (SNP) | VAF 24/541 reads (4%) | called by muse, mutect2
- OFCC1 | n.1945C>G | RNA (SNP) | VAF 9/231 reads (4%) | called by muse, mutect2
- SNRPA1 | c.310-14C>G | Intron (SNP) | VAF 19/498 reads (4%) | called by muse, mutect2
